APOLLO case AP-Y7FN — Proteogenomic analysis of tumors from young women with breast cancer (APOLLO-BRCA-1)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/db2fcff6-4f36-41fe-9633-7c0e3217a478

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Infiltrating duct and tubular carcinoma: ICD-O-3 morphology code: 8522/3; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS.

Biospecimens (2 samples)
- Sample AP-Y7FN-75: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: OCT.
- Sample AP-Y7FN-B7: Tissue type: Normal; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
